Gene-level copy-number profile of tumor specimen HCM-BROD-0758-C43-06A from HCMI case HCM-BROD-0758-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.3 years (20,195 days).
Specimen HCM-BROD-0758-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dd18fbd0-7bc1-44ed-b16a-2af13e045206.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0758-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,387 have no estimate.
https://portal.gdc.cancer.gov/files/d8cef3c4-e957-47bc-9130-254a4ff08efe

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 755; copy number 2: 10,316; copy number 3: 18,614; copy number 4: 19,804; copy number 5: 2,115; copy number 6: 3,711; copy number 7: 493; copy number 8: 1,231; copy number 9: 521; copy number 10: 209; copy number 11: 223; copy number 12: 22; copy number 13: 58; copy number 14: 12; copy number 15: 9; copy number 17: 71; copy number 19: 55; copy number 20: 12; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,057 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:40,970,541–43,691,594, 61 genes, copy number 17 (within-gene range 3–17) (broad region; genes not listed).
- chr3:49,007,062–49,029,706, 7 genes, copy number 17 (within-gene range 3–17): WDR6, DALRD3, MIR425, NDUFAF3, MIR191, IMPDH2, AC137630.3.
- chr7:129,117,513–134,998,153, 109 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr7:137,874,979–138,164,637, 10 genes, copy number 9: CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223, RCC2P3, MIR4468, AC083867.2.
- chr7:139,561,570–142,222,324, 62 genes, copy number 9–10 (broad region; genes not listed).
- chr7:142,320,677–142,871,094, 80 genes, copy number 9 (broad region; genes not listed).
- chr7:142,939,343–146,050,366, 89 genes, copy number 9 (broad region; genes not listed).
- chr7:149,321,865–149,334,857, 2 genes, copy number 9: AC004941.2, NPM1P12.
- chr7:151,375,909–151,413,354, 2 genes, copy number 9 (within-gene range 7–9): WDR86, WDR86-AS1.
- chr12:51,815,043–52,108,261, 17 genes, copy number 11: AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1.
- chr12:56,101,331–56,340,410, 26 genes, copy number 13 (within-gene range 3–13): AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A.
- chr12:57,434,784–60,269,686, 71 genes, copy number 13–19 (broad region; genes not listed).
- chr12:68,686,951–69,579,793, 24 genes, copy number 11–20 (within-gene range 5–20): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2.
- chr12:104,455,295–104,762,014, 1 gene, copy number 15 (within-gene range 5–15): CHST11.
- chr12:104,802,553–107,912,620, 53 genes, copy number 11–21: SLC41A2, Y_RNA, AC089985.1, KRT18P20, C12orf45, ALDH1L2, WASHC4, APPL2, C12orf75, AC078874.1, KCCAT198, CASC18, ST13P3, AC011595.2, NUAK1, AC011595.1, AC010182.1, CKAP4, AC079174.1, AC079174.2, RNU7-94P, TCP11L2, POLR3B, AC079385.1, RFX4, AC079385.2, AC079385.3, RIC8B, AC007695.1, EEF1B2P4, RPL30P12, AC007541.1, TMEM263, MTERF2, CRY1, AC078929.1, SETP7, BTBD11, AC009774.1, RNA5SP371, AC007540.1, Y_RNA, PWP1, AC007622.1, PRDM4, AC007622.2, ASCL4, AC126177.3, AC126177.5, AC126177.2, AC126177.4, AC126177.6, AC126177.1.
- chr12:114,682,292–114,771,851, 4 genes, copy number 10 (within-gene range 4–10): AC026765.3, AC026765.4, AC026765.1, AC026765.2.
- chr12:116,368,764–118,775,137, 45 genes, copy number 10 (within-gene range 10–19): AC079384.1, MIR4472-2, LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2, AC125603.1, SPRING1, RNFT2, AC090013.1, RNU6-558P, AC083806.3, HRK, AC083806.1, FBXW8, AC083806.2, AC127164.1, AC026368.1, TESC, TESC-AS1, FBXO21, NOS1, ELOCP32, AC073864.1, KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1, PEBP1, TAOK3, RPS2P5, AC026367.1, SUDS3, AC026367.3, AC026367.2, LINC02460, RPL17P37, LINC02423, LINC02440.
- chr12:119,959,424–121,298,308, 67 genes, copy number 11 (broad region; genes not listed).
- chr15:20,128,745–22,282,872, 109 genes, copy number 9 (broad region; genes not listed).
- chr16:35,021,749–35,085,060, 5 genes, copy number 9 (within-gene range 2–9): AC135776.1, AC135776.2, AC135776.3, CCNYL3, CLUHP11.
- chr22:18,533,646–18,719,341, 9 genes, copy number 13: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:18,951,934–22,215,270, 204 genes, copy number 9–11 (within-gene range 7–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 755. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
